Somatic mutation profile of tumor specimen TCGA-FZ-5922-01A (aliquot TCGA-FZ-5922-01A-11D-1609-08) from TCGA case TCGA-FZ-5922, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 81.1 years (29,633 days).
Specimen TCGA-FZ-5922-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd64c25f-98da-4c6e-84cd-f76db3b96c01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FZ-5922-11A (Solid Tissue Normal), aliquot TCGA-FZ-5922-11A-01D-1609-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4891070-a728-4624-a004-39bb41763bea

The open-access MAF lists 43 somatic variants for this specimen: 35 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 6, Nonsense Mutation 3, Frame Shift Del 2, Frame Shift Ins 1, Splice Site 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IL2RA | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 75/449 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773957702, COSV99906388; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 24/181 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TGFBR1 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 55/229 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs113605875, CM050757, CM063198, COSV66625173; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGPAT3 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 223/1298 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV99377016, COSV99377709; called by muse, mutect2, varscan2
- AP1B1 | c.2500C>G p.L834V | Missense Mutation (SNP) | VAF 232/1476 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs770850540, COSV100434255; called by muse, mutect2, varscan2
- ARID1A | c.5777del p.G1926Efs*30 | Frame Shift Del (DEL) | VAF 151/781 reads (19%) | catalogued as COSV61389545, COSV61392751; called by mutect2, pindel, varscan2
- BAP1 | c.932-2A>C p.X311_splice | Splice Site (SNP) | VAF 168/711 reads (24%) | catalogued as COSV56235815, COSV56242065; called by muse, mutect2, varscan2
- CLEC1B | c.596A>G p.H199R | Missense Mutation (SNP) | VAF 139/819 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV100045849; called by muse, mutect2, varscan2
- CTNNB1 | c.1856G>A p.C619Y | Missense Mutation (SNP) | VAF 181/1029 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.391); catalogued as COSV100845897; called by muse, mutect2, varscan2
- DISP2 | c.4050C>G p.D1350E | Missense Mutation (SNP) | VAF 49/895 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.292); catalogued as COSV99139624; called by muse, mutect2
- DNAH3 | c.3956C>T p.A1319V | Missense Mutation (SNP) | VAF 80/360 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as rs376419884; called by muse, mutect2, varscan2
- DSPP | c.707A>T p.D236V | Missense Mutation (SNP) | VAF 58/288 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.282); catalogued as COSV99216152; called by muse, mutect2, varscan2
- FAT2 | c.9691G>A p.A3231T | Missense Mutation (SNP) | VAF 43/272 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs1367931827, COSV99941199; called by muse, mutect2, varscan2
- GMPPA | c.1090G>T p.D364Y | Missense Mutation (SNP) | VAF 89/477 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.106); catalogued as COSV100354408, COSV58007484; called by muse, mutect2, varscan2
- GRM8 | c.1589A>C p.K530T | Missense Mutation (SNP) | VAF 19/754 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV100279250; called by muse, mutect2
- HYAL4 | c.500C>G p.S167* | Nonsense Mutation (SNP) | VAF 116/631 reads (18%) | catalogued as COSV56139982, COSV99771993; called by muse, mutect2, varscan2
- KIF26B | c.4304T>A p.M1435K | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs574497869, COSV100831432, COSV100833637; called by muse, mutect2, varscan2
- LIAS | c.157C>G p.L53V | Missense Mutation (SNP) | VAF 139/819 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV54695458, COSV99787468; called by muse, mutect2, varscan2
- LNX2 | c.1594C>T p.H532Y | Missense Mutation (SNP) | VAF 89/541 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.38); catalogued as COSV100310374; called by muse, mutect2, varscan2
- LONRF3 | c.1519G>A p.G507S (on ENST00000371628 / NM_001031855.3; = p.G466S on NM_024778.5) | Missense Mutation (SNP) | VAF 284/810 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs764430995, COSV100504162; called by muse, mutect2, varscan2
- MPZL1 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 67/360 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV100850301; called by muse, mutect2, varscan2
- NDUFA4 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 100/1327 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs368918684; called by muse, mutect2
- NUP153 | c.208A>G p.T70A | Missense Mutation (SNP) | VAF 44/827 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs138192099; called by muse, mutect2
- PPIL2 | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 149/802 reads (19%) | catalogued as COSV100256007; called by muse, mutect2, varscan2
- PTPRE | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 93/517 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs200125787, COSV54561395; called by muse, mutect2, varscan2
- RAB6B | c.188G>C p.R63P | Missense Mutation (SNP) | VAF 72/445 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99557700; called by muse, mutect2, varscan2
- RING1 | c.1196A>G p.Y399C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV63003104; called by muse, mutect2, varscan2
- SOX5 | c.1300C>G p.P434A | Missense Mutation (SNP) | VAF 30/904 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as COSV100505258, COSV58630026; called by muse, mutect2
- SUN1 | c.1618G>A p.D540N (on ENST00000405266 / NM_001367651.1; = p.D420N on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 177/1020 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.318); catalogued as COSV67448525; called by muse, mutect2, varscan2
- TNPO3 | c.311T>A p.I104N | Missense Mutation (SNP) | VAF 71/399 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99602238; called by muse, mutect2, varscan2
- ZNF276 | c.620C>T p.A207V (on ENST00000443381 / NM_001113525.2; = p.A132V on NM_152287.4) | Missense Mutation (SNP) | VAF 82/485 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57068698; called by muse, mutect2, varscan2
- ELMO3 | c.2087_2107del p.F696_E703delins* (on ENST00000652269; = p.F643_E650delins* on NM_024712.5) | Nonsense Mutation (DEL) | VAF 72/539 reads (13%) | called by mutect2, pindel
- MRPL35 | c.181dup p.T61Nfs*4 | Frame Shift Ins (INS) | VAF 153/1047 reads (15%) | called by mutect2, pindel, varscan2
- NEURL4 | c.2213G>T p.R738L | Missense Mutation (SNP) | VAF 99/831 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TNIK | c.3979del p.L1327Yfs*24 | Frame Shift Del (DEL) | VAF 56/464 reads (12%) | called by mutect2, pindel, varscan2
- DGUOK | c.678C>T p.H226= | Silent (SNP) | VAF 41/234 reads (18%) | catalogued as rs372217661, COSV99903461; called by muse, mutect2, varscan2
- ECEL1 | c.351C>T p.D117= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV100458322; called by muse, mutect2
- GDI2 | c.1305G>A p.K435= | Silent (SNP) | VAF 161/998 reads (16%) | catalogued as COSV100049789; called by muse, mutect2, varscan2
- MAP3K4 | c.4171T>C p.L1391= | Silent (SNP) | VAF 186/823 reads (23%) | catalogued as rs753455985, COSV62340591; called by muse, mutect2, varscan2
- SCFD2 | c.360G>A p.A120= | Silent (SNP) | VAF 75/342 reads (22%) | catalogued as rs1188134914, COSV101189154; called by muse, mutect2, varscan2
- TXNRD1 | c.321G>A p.L107= (on ENST00000525566 / NM_001093771.3; = p.L9= on NM_003330.4) | Silent (SNP) | VAF 131/839 reads (16%) | catalogued as COSV100723178; called by muse, mutect2, varscan2
- DCHS2 | n.5515C>T | RNA (SNP) | VAF 48/255 reads (19%) | catalogued as COSV100600829; called by muse, mutect2, varscan2
- RUBCNL | c.-122-5340A>G | Intron (SNP) | VAF 13/112 reads (12%) | catalogued as COSV100528701; called by muse, mutect2, varscan2
